Somatic mutation profile of tumor specimen MMRF_1652_1_BM_CD138pos (aliquot MMRF_1652_1_BM_CD138pos_T1_KBS5U_L04402) from MMRF case MMRF_1652, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,069 days).
Specimen MMRF_1652_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ae6e6f3-7ba2-48f0-ad04-f42861b6a553.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1652_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1652_2_PB_Whole_C1_KBS5U_L04406; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7db890e9-c864-4ee9-ae79-8f19873d289a

The open-access MAF lists 132 somatic variants for this specimen: 58 protein-altering or splice-affecting, 23 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 30, Silent 23, Intron 11, 5'UTR 8, Frame Shift Del 3, Splice Site 2, 3'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDRT4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1242429300, COSV100381519; called by muse, mutect2, varscan2
- CIART | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.541); catalogued as COSV51743973; called by muse, mutect2, varscan2
- DCAF8L2 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV70552910; called by muse, mutect2, varscan2
- DCDC1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770336113, COSV60841140; called by muse, mutect2, varscan2
- DDC | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV63568246; called by muse, mutect2, varscan2
- DENND1C | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780582383; called by muse, mutect2, varscan2
- EEF1A1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV58548873, COSV58549955; called by muse, mutect2, varscan2
- FAM71A | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs201631987, COSV99674860; called by muse, mutect2, varscan2
- FRMD4A | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV62267437; called by muse, mutect2, varscan2
- HAPLN4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs144698679; called by muse, mutect2, varscan2
- IGLL5 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2, varscan2
- MAGEC1 | c.319del p.D107Tfs*6 | Frame Shift Del (DEL) | VAF 81/225 reads (36%) | catalogued as COSV53582056, COSV99596029; called by mutect2, pindel, varscan2
- MFSD10 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1251324236; called by muse, mutect2, varscan2
- NDUFAF7 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as COSV50016944; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PLA2G4D | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs143243064, COSV99299786; called by mutect2, varscan2
- RYR1 | c.14716G>A p.A4906T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1467742744, COSV100617115; called by muse, mutect2, varscan2
- SKIV2L | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1373847630, COSV100514829; called by muse, varscan2
- SLC2A8 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753755259; called by muse, mutect2, varscan2
- TRIM7 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs1278951787; called by muse, mutect2, varscan2
- WDR87 | c.5567G>A p.R1856K | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.172); catalogued as COSV58194247; called by muse, mutect2
- ZNF274 | c.1487C>A p.T496K (on ENST00000610905; = p.T391K on NM_016324.3) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100465225; called by muse, mutect2, varscan2
- ADCY2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 26/433 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARL2BP | c.38+4_38+32del p.X13_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel
- C4orf54 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DHX15 | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ2 | c.7195G>C p.E2399Q (on ENST00000467148 / NM_001037335.2; = p.E1830Q on NM_033405.3) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- IGHV1-69D | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- IGHV2-70D | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- IGHV2-70D | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, varscan2
- IGLV4-3 | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 114/167 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIAA0100 | c.3506G>T p.S1169I | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LAS1L | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- LIPC | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MFSD5 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MGAT5B | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- MIEF2 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); called by muse, mutect2
- MITF | c.1198A>T p.I400F (on ENST00000448226 / NM_006722.3; = p.I300F on NM_000248.4) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MORC2 | c.1589A>G p.D530G (on ENST00000397641 / NM_001303256.3; = p.D468G on NM_014941.3) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MVB12B | c.758-3C>T | Splice Region (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- NIPAL2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- NTN4 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR4A47 | c.190T>A p.L64I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- RBM41 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RGS22 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SI | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SLC26A4 | c.1945A>C p.N649H | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SLC9A4 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SMC1A | c.2420+1G>A p.X807_splice | Splice Site (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.2317C>A p.P773T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D31 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGOLN2 | c.947A>C p.E316A | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TRMT1 | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- UBR4 | c.8581del p.T2861Pfs*115 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- WNK3 | c.2488G>A p.V830I | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- ZFP42 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF254 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZNF317 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD30A | c.3882A>G p.Q1294= (on ENST00000611781; = p.Q1238= on NM_052997.2) | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs116842461; called by muse, mutect2, varscan2
- CANX | c.117T>A p.I39= | Silent (SNP) | VAF 13/358 reads (4%) | called by muse, mutect2
- CCDC9B | c.840G>A p.R280= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1208908601; called by muse, mutect2, varscan2
- DNAJA4 | c.780C>A p.I260= (on ENST00000343789; = p.I289= on NM_018602.3) | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV59424905, COSV59427480; called by muse, mutect2, varscan2
- ERCC6 | c.4086A>G p.G1362= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- FMN1 | c.1491G>A p.P497= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs755666287; called by muse, mutect2, varscan2
- GLT6D1 | c.345G>A p.V115= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- HTRA3 | c.1173T>C p.V391= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.99C>G p.P33= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as rs771235208; called by muse, mutect2, varscan2
- IGLV3-1 | c.237A>T p.R79= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs544600967; called by muse, mutect2, varscan2
- IQSEC2 | c.2832C>T p.N944= (on ENST00000642864 / NM_001111125.3; = p.N739= on NM_015075.2) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs782519675; ClinVar: benign; called by muse, mutect2, varscan2
- KLF14 | c.729C>T p.A243= | Silent (SNP) | VAF 3/55 reads (5%) | called by muse, mutect2
- MYH14 | c.996C>T p.N332= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs200900231, COSV51813512; called by muse, mutect2, varscan2
- NPR2 | c.1179C>T p.V393= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- PPP6R1 | c.1116C>T p.A372= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PRKDC | c.3279G>A p.E1093= | Silent (SNP) | VAF 72/183 reads (39%) | called by muse, mutect2, varscan2
- SPEM1 | c.88C>T p.L30= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as rs779053777; called by muse, mutect2, varscan2
- TAAR2 | c.490C>T p.L164= (on ENST00000367931 / NM_001033080.1; = p.L119= on NM_014626.3) | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs972643893; called by muse, mutect2, varscan2
- TBX22 | c.438G>A p.P146= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs201942455, COSV100960888, COSV100960938; called by muse, mutect2, varscan2
- TCP11 | c.363G>A p.L121= (on ENST00000512012; = p.L59= on NM_018679.5) | Silent (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- THBD | c.1365C>T p.C455= | Silent (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- TM2D1 | c.75C>T p.F25= | Silent (SNP) | VAF 67/152 reads (44%) | called by muse, mutect2, varscan2
- YME1L1 | c.531T>C p.R177= (on ENST00000326799 / NM_139312.3; = p.R120= on NM_014263.4) | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- ABCD3 | c.*1242dup | 3'UTR (INS) | VAF 30/62 reads (48%) | called by mutect2, varscan2
- ADAMTS2 | c.*1199T>C | 3'UTR (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- AP2A1 | c.2115-142G>A | Intron (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- ATAD2B | c.*268A>T | 3'UTR (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- BAGE2 | n.331T>A | RNA (SNP) | VAF 44/466 reads (9%) | called by muse, varscan2
- BCL9L | c.*3021A>G | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- CARD10 | c.*727C>T | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs571780934; called by muse, mutect2, varscan2
- CDC42SE2 | c.-271T>C | 5'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- CEP41 | c.*1344A>T | 3'UTR (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99782608; called by muse, mutect2, varscan2
- CERS6 | c.*881C>A | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- CHP2 | c.*551G>A | 3'UTR (SNP) | VAF 33/60 reads (55%) | catalogued as rs954702861; called by muse, mutect2, varscan2
- CNOT11 | c.*827G>A | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DBF4 | c.*595dup | 3'UTR (INS) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- DBF4B | c.-8G>T | 5'UTR (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2
- DBT | c.939+1202C>T | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DBT | c.939+1201G>A | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DCP2 | c.*2630G>A | 3'UTR (SNP) | VAF 34/132 reads (26%) | catalogued as rs1016993502; called by muse, mutect2, varscan2
- DDIT4 | c.-100A>G | 5'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, varscan2
- DR1 | chr1:93362215 G>A | 3'Flank (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- DYRK2 | c.-168G>A | 5'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- GPR17 | c.*394C>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- HGF | c.*1747G>A | 3'UTR (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- HRH1 | c.*2240C>T | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- IDH3G | c.233+39G>A | Intron (SNP) | VAF 62/123 reads (50%) | called by muse, mutect2, varscan2
- IL36RN | c.*1560C>A | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+203T>C | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- NAP1L1 | c.*2683C>T | 3'UTR (SNP) | VAF 59/156 reads (38%) | called by muse, mutect2, varscan2
- NBEA | c.*559_*563del | 3'UTR (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel*, varscan2*
- NMNAT2 | c.*1428C>A | 3'UTR (SNP) | VAF 60/107 reads (56%) | catalogued as COSV54271534; called by muse, mutect2, varscan2
- PHC3 | c.537+199C>G | Intron (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- PIK3R3 | c.-613A>G | 5'UTR (SNP) | VAF 8/44 reads (18%) | catalogued as rs1323926154; called by muse, mutect2
- PRMT6 | chr1:107056668 del CGCGCCGTGCCGCG | 5'UTR (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- PTK2 | c.*965_*966del | 3'UTR (DEL) | VAF 18/50 reads (36%) | called by pindel, varscan2
- RXFP1 | c.*1096_*1098del | 3'UTR (DEL) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- SCN3B | c.*8G>A | 3'UTR (SNP) | VAF 72/196 reads (37%) | catalogued as rs1288973934; called by muse, mutect2, varscan2
- SH2D1A | c.*480G>A | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- SLC13A2 | c.*347T>A | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- SOX11 | c.*4239del | 3'UTR (DEL) | VAF 22/42 reads (52%) | catalogued as rs536771967; called by mutect2, varscan2
- SRRD | c.251-21T>G | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SULT2B1 | c.72-75G>A | Intron (SNP) | VAF 8/86 reads (9%) | catalogued as rs369311536; called by muse, mutect2
- TCP1 | c.64+106G>A | Intron (SNP) | VAF 10/57 reads (18%) | catalogued as rs1327094070; called by muse, mutect2, varscan2
- TMX2 | c.*250C>T | 3'UTR (SNP) | VAF 102/289 reads (35%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.-135_-132del | 5'UTR (DEL) | VAF 42/128 reads (33%) | called by mutect2, pindel, varscan2
- TNFSF8 | c.*783C>T | 3'UTR (SNP) | VAF 62/113 reads (55%) | called by muse, mutect2, varscan2
- TNKS | c.*430G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- TOMM40L | c.*924del | 3'UTR (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- TRMT1 | c.254+42T>C | Intron (SNP) | VAF 78/123 reads (63%) | called by muse, mutect2, varscan2
- VAPA | c.*2321T>A | 3'UTR (SNP) | VAF 58/112 reads (52%) | called by muse, mutect2, varscan2
- WDFY3 | c.*88C>T | 3'UTR (SNP) | VAF 52/114 reads (46%) | catalogued as rs1216599777, COSV55700698; called by muse, mutect2, varscan2
- ZIC2 | c.-1C>T | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- ZNF430 | c.322+13G>A | Intron (SNP) | VAF 136/477 reads (29%) | called by muse, mutect2, varscan2
